Somatic mutation profile of tumor specimen ALCH-AFDT-TTP1-A (aliquot ALCH-AFDT-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AFDT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 70.5 years (25,759 days).
Specimen ALCH-AFDT-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 883d2944-fe36-4592-8d83-071820e6d1e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFDT-NB1-A (Blood Derived Normal), aliquot ALCH-AFDT-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd948875-322a-4c4f-9567-d42f5c6a7a8d

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCTD1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776999, CM132530, CM132535, CM132538, COSV58690237; ClinVar: pathogenic; called by muse, mutect2
- ELP4 | c.784G>A p.G262S (on ENST00000350638; = p.G261S on NM_019040.5) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs375868750; called by muse, mutect2
- HTR2C | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1556487133, COSV52208053; called by muse, mutect2, varscan2
- RBM10 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | catalogued as COSV61308085; called by muse, mutect2
- VSIG4 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as rs1296430566; called by muse, mutect2
- ABCA7 | c.5482G>T p.V1828L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ACKR1 | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- CLTC | c.1261C>T p.L421F | Missense Mutation (SNP) | VAF 38/465 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EIF4ENIF1 | c.2044C>A p.P682T | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- HSPA4 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNMA1 | c.1961T>A p.I654N | Missense Mutation (SNP) | VAF 17/508 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LATS2 | c.2065G>C p.D689H | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAPK7 | c.2258A>T p.Q753L | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2
- MBD5 | c.979A>G p.M327V | Missense Mutation (SNP) | VAF 16/469 reads (3%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2
- SENP6 | c.2558A>G p.N853S | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- SZT2 | c.9490G>A p.D3164N (on ENST00000634258 / NM_001365999.1; = p.D3107N on NM_015284.4) | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR31 | c.579C>T p.I193= | Silent (SNP) | VAF 19/271 reads (7%) | catalogued as rs768719314; called by muse, mutect2
- MAGT1 | c.580T>C p.L194= (on ENST00000618282 / NM_001367916.1; = p.L226= on NM_032121.5) | Silent (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- SLC2A12 | c.387C>G p.S129= | Silent (SNP) | VAF 20/285 reads (7%) | called by muse, mutect2
- ADAM10 | c.484+2884C>T | Intron (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
